Gene-level copy-number profile of tumor specimen ALCH-B4AG-TTP1-A from ALCHEMIST case ALCH-B4AG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.8 years (21,849 days).
Specimen ALCH-B4AG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e957188e-6299-4b04-95f2-9c12b748c187.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4AG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,286 have no estimate.
https://portal.gdc.cancer.gov/files/86b212c9-3639-4b0e-857f-bd94db4ae1ef

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 478; copy number 1: 29,942; copy number 2: 26,087; copy number 3: 1,267; copy number 4: 422; copy number 5: 71; copy number 6: 27; copy number 7: 12; copy number 8: 7; copy number 9: 5; copy number 11: 9; copy number 12: 1; copy number 14: 3; copy number 15: 1; copy number 17: 1; copy number 21: 2; copy number 25: 1; copy number 31: 1.

Homozygous deletions (total copy number 0; autosomes only): 436 genes in 104 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,059,708–1,069,355, 2 genes: AL390719.1, AL645608.8.
- chr1:1,253,909–1,280,420, 2 genes: UBE2J2, LINC01786.
- chr2:241,581,922–241,637,158, 3 genes: AC133528.1, THAP4, RNA5SP122.
- chr3:51,385,291–51,500,002, 3 genes: MANF, RBM15B, DCAF1.
- chr3:75,521,803–75,670,185, 14 genes: SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26.
- chr4:188,091,273–188,147,743, 5 genes: TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1.
- chr5:1,798,385–1,851,497, 3 genes: MRPL36, NDUFS6, AC025183.1.
- chr8:54,130,582–54,152,882, 3 genes: Metazoa_SRP, MRPL15, RNU6ATAC32P.
- chr9:38,360,427–39,655,531, 36 genes: AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A, FAM201A, YWHABP1, RNU6-765P, AL845311.1, VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8.
- chr9:42,384,805–42,499,134, 5 genes: FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.
- chr9:42,725,013–61,666,386, 31 genes: BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1, FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr9:61,898,805–63,385,117, 42 genes (within-gene range 0–1): FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4, BMS1P10, AQP7P1, AL845321.1.
- chr9:63,728,877–64,765,535, 26 genes: AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr9:66,721,158–68,300,035, 30 genes: ATP5F1AP10, SDR42E1P4, FKBP4P8, ZNF658, BX664608.1, AL353770.4, AL353770.2, FAM74A3, AL353770.3, AL353770.1, SPATA31A3, CNTNAP3P2, RN7SL422P, AL162233.1, RBM17P2, BX005195.1, BX664730.1, Y_RNA, FAM27E3, AL627230.3, FAM27B, AL627230.1, RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4.
- chr9:138,129,399–138,253,217, 6 genes: AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr10:80,046,860–80,205,572, 7 genes: TMEM254-AS1, AL356095.3, TMEM254, AL356095.2, RPL22P18, PLAC9, ANXA11.
- chr10:84,194,537–84,225,544, 2 genes: CDHR1, LRIT2.
- chr10:92,418,667–92,574,096, 2 genes: MARK2P9, IDE.
- chr10:92,689,955–92,710,608, 2 genes: HHEX, Y_RNA.
- chr10:98,383,565–98,453,805, 5 genes (within-gene range 0–1): PYROXD2, MIR1287, HPS1, MIR4685, AL139243.1.
- chr11:70,467,856–71,252,577, 10 genes (within-gene range 0–1): SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr12:118,063,593–118,145,584, 3 genes (within-gene range 0–1): VSIG10, AC131238.1, PEBP1.
- chr12:126,864,465–126,912,322, 4 genes: AC078878.1, LINC02372, AC078878.2, HSPE1P20.
- chr12:127,372,243–127,826,286, 8 genes: AC048347.1, AC068787.1, AC025252.1, Y_RNA, AC025252.2, LINC02411, AC087894.3, AC087894.2.
- chr12:128,023,788–129,904,025, 27 genes (within-gene range 0–1): LINC02441, LINC02369, LINC02368, AC061709.2, AC061709.1, TMEM132C, AC061709.3, MIR3612, AC023595.1, AC090424.1, SLC15A4, AC108704.2, AC108704.1, GLT1D1, AC069262.1, NLRP9P1, TMEM132D, TMEM132D-AS1, AC107033.1, TMEM132D-AS2, AC079456.1, AC130404.1, AC130404.2, AC117373.1, AC117373.2, AC055717.3, AC055717.1.
- chr12:130,121,925–130,165,740, 5 genes: AC026336.4, AC026336.3, FZD10-AS1, AC026336.5, FZD10.
- chr12:130,249,679–130,383,890, 4 genes: AC026336.2, PIWIL1, AC127071.2, AC127071.3.
- chr16:715,118–726,954, 3 genes (within-gene range 0–2): METRN, ANTKMT, CCDC78.
- chr16:1,088,226–1,113,399, 3 genes: C1QTNF8, AL031713.1, AL031598.1.
- chr16:46,469,341–46,790,407, 13 genes (within-gene range 0–1): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3.
- chr17:142,789–386,254, 7 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.
- chr17:12,973,033–13,018,065, 4 genes (within-gene range 0–1): AC005274.1, AC005277.2, AC005277.1, ELAC2.
- chr17:16,414,524–16,437,003, 3 genes: AC093484.2, TRPV2, AC093484.1.
- chr17:36,486,629–36,543,435, 4 genes (within-gene range 0–1): ZNHIT3, RNA5SP439, MYO19, PIGW.
- chr17:37,977,972–38,257,192, 10 genes: TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA.
- chr19:39,306,566–39,342,372, 3 genes (within-gene range 0–2): LRFN1, GMFG, AC011445.1.
- chr19:52,336,243–52,418,412, 5 genes (within-gene range 0–1): ZNF610, ZNF880, ZNF528-AS1, AC010332.1, ZNF528.
- chr19:56,176,008–56,217,777, 4 genes: GALP, ZSCAN5B, ZSCAN5C, AC011506.1.
- chr20:407,498–462,543, 3 genes: RBCK1, TBC1D20, Y_RNA.
- chr21:10,413,477–10,613,379, 5 genes: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 1,830 genes in 153 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:172,137,345–173,052,893, 14 genes, copy number 3: AC104088.1, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2.
- chr2:175,842,887–202,336,727, 403 genes, copy number 3–5 (broad region; genes not listed).
- chr2:202,376,327–207,167,267, 93 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr3:174,302,944–175,810,548, 15 genes, copy number 3: ANAPC15P2, AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1.
- chr3:176,113,702–177,228,000, 9 genes, copy number 3: AC117434.1, LINC01208, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P.
- chr3:177,441,910–179,650,200, 39 genes, copy number 3–4: LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13.
- chr3:179,794,958–180,542,836, 11 genes, copy number 3: PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2, AC092939.1, RNA5SP149, AC134503.1, GAPDHP36, RALBP1P1, LINC02053, U8.
- chr3:180,707,589–181,836,880, 19 genes, copy number 3 (within-gene range 2–3): AC108734.4, RN7SL229P, AC108734.3, AC108734.2, FLYWCH1P1, FXR1, AC108734.1, DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2.
- chr3:181,822,872–182,985,953, 21 genes, copy number 3–4: RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1.
- chr3:183,178,043–183,616,742, 12 genes, copy number 3: MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1.
- chr3:185,162,871–185,552,588, 8 genes, copy number 3: EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4, TMEM41A, LIPH.
- chr3:185,643,130–190,832,173, 90 genes, copy number 3–5 (broad region; genes not listed).
- chr3:193,144,464–194,832,592, 49 genes, copy number 3: AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036, LINC02037, LINC02048, LINC00887, AC117469.1, CPN2, LRRC15, GP5, ATP13A3, AC108676.2, LINC00884, AC108676.1, RNU6-1101P, RPL23AP93, TMEM44-AS1, TMEM44, AC046143.1, AC046143.2, LSG1, FAM43A, AC106706.1, AC106706.2, LINC01968, AC090505.1, LINC01972, AC090505.2.
- chr3:195,274,745–195,651,472, 13 genes, copy number 3–4: ACAP2, ACAP2-IT1, AC090018.1, Y_RNA, PPP1R2, RNU6ATAC24P, AC069213.1, RN7SL73P, AC069213.3, AC069213.2, APOD, MUC20P1, AC233280.2.
- chr3:195,720,884–196,082,096, 17 genes, copy number 3 (within-gene range 2–3): MUC20, MUC4, LINC01983, KIF3AP1, TNK2, MIR6829, AC124944.3, TNK2-AS1, AC124944.2, RNU2-11P, AC124944.1, SDHAP1, AC024937.3, AC024937.2, TFRC, AC024937.1, RNU7-18P.
- chr3:196,211,487–196,832,647, 32 genes, copy number 3: SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P, UBXN7, RNU6-1279P, RN7SL434P, RN7SL738P, AC083822.1, UBXN7-AS1, AC117490.1, RNF168, AC117490.2, SMCO1, AC092933.1, RPS29P3, WDR53, FBXO45, LINC01063, NRROS, PIGX, CEP19, RNU6-646P, PAK2, RNU4-89P, RNU6-42P.
- chr3:196,983,890–197,888,436, 24 genes, copy number 3: RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1.
- chr5:39,284,140–45,895,970, 93 genes, copy number 4–5 (broad region; genes not listed).
- chr8:112,148,742–114,791,929, 12 genes, copy number 3–4: RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2.
- chr8:127,072,694–130,655,712, 47 genes, copy number 3–5: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1.
- chr8:132,685,007–133,963,259, 29 genes, copy number 3–4: TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2.
- chr8:134,722,947–135,656,722, 14 genes, copy number 3–4: AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1.
- chr8:142,611,049–143,160,711, 31 genes, copy number 3–8: ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4, AC083841.3, GML, ZNHIT1P1, CYP11B1, CYP11B2, LY6E-DT, CDC42P3, LY6E, C8orf31, AK3P2, AC083982.1, LY6L, LY6H.
- chr8:143,734,139–144,465,667, 54 genes, copy number 3–9 (within-gene range 2–10): IQANK1, AC105219.3, SCRIB, MIR937, PUF60, AC234917.3, AC234917.1, NRBP2, MIR6845, AC234917.2, EPPK1, PLEC, MIR661, PARP10, GRINA, SPATC1, SMPD5, OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1, CYC1, SHARPIN, MAF1, WDR97, HGH1, TSSK5P, MROH1, BOP1, MIR7112, SCX, HSF1, DGAT1, AC233992.1, MIR6848, SCRT1, SLC52A2, TMEM249, AC233992.2, FBXL6, ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1.
- chr8:144,502,973–144,605,816, 9 genes, copy number 3–7 (within-gene range 0–7): GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82, ARHGAP39, AC084125.3.
- chr9:33,218,365–36,124,455, 154 genes, copy number 3–4 (broad region; genes not listed).
- chr9:41,890,314–42,354,454, 9 genes, copy number 3: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2.
- chr11:34,915,829–35,530,300, 11 genes, copy number 3 (within-gene range 2–3): PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1.
- chr13:109,478,739–111,115,678, 35 genes, copy number 3–8 (within-gene range 2–8): AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431, LINC00368, AL353704.2, ARHGEF7-AS2.
- chr13:112,313,467–113,277,734, 26 genes, copy number 3–6: LINC01043, LINC01044, SPACA7, TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1.
- chr13:113,324,163–113,737,736, 13 genes, copy number 3–4: GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1.
- chr13:113,864,112–114,337,626, 15 genes, copy number 3–5: GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, RASA3, RASA3-IT1, CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:104,865,268–105,181,194, 14 genes, copy number 3–5 (within-gene range 1–5): CEP170B, AL583810.3, PLD4, AHNAK2, CLBA1, CDCA4, GPR132, LINC02298, AL512356.4, AL512356.3, AL512356.2, JAG2, MIR6765, AL512356.1.
- chr17:40,309,180–40,439,917, 11 genes, copy number 3–7: RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, TOP2A, Y_RNA, RPL23AP75.
- chr17:40,475,828–40,703,752, 10 genes, copy number 4: TNS4, AC004585.1, CCR7, AC004585.2, SMARCE1, AC073508.2, AC073508.3, KRT222, AC073508.1, KRT24.
- chr17:41,065,116–41,187,136, 15 genes, copy number 3–4: KRTAP2-4, KRTAP4-7, AC100808.1, KRTAP4-8, KRTAP4-16, KRTAP4-9, KRTAP4-11, KRTAP4-12, KRTAP4-6, KRTAP4-5, KRTAP4-4, KRTAP4-3, KRTAP4-2, KRTAP4-1, KRTAP4-17P.
- chr17:48,548,870–48,606,414, 8 genes, copy number 3–4 (within-gene range 2–4): HOXB3, HOXB-AS3, HOXB-AS2, HOXB4, AC103702.1, MIR10A, HOXB5, HOXB6.
- chr19:984,332–1,279,244, 22 genes, copy number 3–25: WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2, STK11, HMGB2P1, CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr19:1,724,115–1,926,013, 16 genes, copy number 3–4: Metazoa_SRP, AC005256.1, ONECUT3, ATP8B3, REXO1, AC012615.2, MIR1909, AC012615.6, AC012615.3, KLF16, AC012615.4, AC012615.1, AC012615.5, ABHD17A, SCAMP4, ADAT3.
- chr19:35,738,801–35,758,079, 9 genes, copy number 3–5 (within-gene range 1–5): IGFLR1, AD000671.2, U2AF1L4, PSENEN, AD000671.1, AD000671.3, LIN37, AC002398.2, HSPB6.

Autosomal genes at a single copy (total copy number 1): 27,640. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
